Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3UY, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3UY-01A (Primary Tumor).

[page 1 of 2]
tiPAA Discrepancy		☒

Head & Neck
Head And Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Papillary thyroid cancer.

Specimens Submitted:

1: Thyroid gland; total thyroidectomy

DIAGNOSIS:

1. Thyroid gland; total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 1.2 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Adenoma(s) (away from the carcinoma):

Not identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

Identified

ICD-O-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9 5.2-12
RD

[page 2 of 2]
One normocellular parathyroid gland adjacent to isthmus

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1). The specimen is received fresh, labeled "thyroid gland", and consists of a thyroid weighing 14.5 g. The right lobe measures 3.5 x 2.0 x 1.1 cm, the left lobe measures 3.6 x 2.2 x 1.2 cm and the isthmus measures 2.2 x 2.0 x 1.0 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 1.2 x 0.7 x 0.6 cm gray-tan fairly well-circumscribed and non-encapsulated nodule. The nodule is located in the left lobe. The remaining thyroid parenchyma is red brown and beefy. Representative sections of the specimen are submitted for The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N - nodule, entirely submitted

RL - right lobe

LL - left lobe

IS - isthmus

Summary of Sections:

Part 1: Thyroid gland; total thyroidectomy

Block	Sect. Site	PCs
1	IS	2
3	LL	4
3	N	4
3	RL	5

Source: NCI Genomic Data Commons file 6bdb6a43-4e87-42be-a2f5-068ac17f1760 (TCGA-DJ-A3UY.31C6D2B0-71BA-4E3E-A3FA-911F3B2B1BFC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).